BEATAML1.0 case 2171 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/d3b0efc9-b81d-4527-9524-756f93a79a2d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Acute myeloid leukemia with myelodysplasia-related changes: ICD-O-3 morphology code: 9895/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.0 years (24,098 days); Progression or recurrence: no; ELN risk classification: Adverse.

Biospecimens (2 samples)
- Sample BA2790D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
- Sample BA2900D: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
